Somatic mutation profile of tumor specimen TCGA-HE-A5NJ-01A (aliquot TCGA-HE-A5NJ-01A-11D-A26P-10) from TCGA case TCGA-HE-A5NJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS.
Specimen TCGA-HE-A5NJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f7b67cd-58b1-4545-914e-3f1dfc3c41a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-A5NJ-10A (Blood Derived Normal), aliquot TCGA-HE-A5NJ-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4320dc1f-65fb-4961-885d-a7565cb0da35

The open-access MAF lists 73 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, 3'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR2A | c.954A>G p.I318M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV54020758, COSV54022133; called by muse, mutect2, varscan2
- ALMS1 | c.12475C>T p.Q4159* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as COSV52509498; called by muse, mutect2, varscan2
- ARHGAP32 | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV59847466; called by muse, mutect2
- C19orf71 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 109/324 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV61535489; called by muse, mutect2
- C1orf185 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.788); catalogued as COSV65624523; called by muse, mutect2, varscan2
- CD36 | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 94/144 reads (65%) | catalogued as COSV59212833; called by muse, varscan2
- CREBBP | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs865788612, COSV52123131; called by muse, mutect2, varscan2
- CRPPA | c.1171C>G p.L391V (on ENST00000407010 / NM_001368197.1; = p.L341V on NM_001101417.4) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1247403699, COSV67905861; called by muse, mutect2, varscan2
- DNAH3 | c.4644G>T p.L1548F | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54520400; called by muse, mutect2, varscan2
- ENPEP | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1262483526, COSV54450776; called by muse, mutect2, varscan2
- FAM155B | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 77/88 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV52936070; called by muse, mutect2, varscan2
- FXR2 | c.1024A>C p.M342L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV51468224; called by muse, mutect2, varscan2
- GPN1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53114599; called by muse, mutect2, varscan2
- GPR83 | c.1165A>T p.N389Y | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54718597, COSV54720922; called by muse, mutect2, varscan2
- IFT81 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 32/105 reads (30%) | catalogued as rs372027811; called by muse, mutect2, varscan2
- IGF2R | c.1968G>C p.K656N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.413); catalogued as COSV63628949; called by muse, mutect2, varscan2
- IGSF10 | c.7153A>C p.S2385R | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.234); catalogued as COSV56378235; called by muse, mutect2, varscan2
- IL27RA | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV54600651; called by muse, mutect2, varscan2
- ITPR1 | c.7849G>A p.E2617K (on ENST00000354582; = p.E2562K on NM_002222.7) | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56980760; called by muse, mutect2, varscan2
- MYH4 | c.659A>C p.E220A | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55117848; called by muse, mutect2, varscan2
- MYPN | c.3298C>T p.P1100S | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62733720; called by muse, mutect2, varscan2
- NEDD4L | c.1940G>C p.R647T (on ENST00000400345 / NM_001144967.3; = p.R627T on NM_015277.6) | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56844510; called by muse, mutect2
- NUP210L | c.898A>G p.R300G | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV55147159; called by muse, mutect2, varscan2
- NUSAP1 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV52971158; called by muse, mutect2, varscan2
- OLFM4 | c.1454C>A p.P485H | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54577262, COSV99524582; called by muse, mutect2, varscan2
- PAPLN | c.328T>G p.Y110D | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53717612; called by muse, mutect2
- PAXIP1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs540417697, COSV68186006; called by muse, mutect2, varscan2
- PIWIL4 | c.1771A>G p.I591V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV54409208; called by muse, mutect2, varscan2
- POLA1 | c.1708T>A p.L570M | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT tolerated (0.25); PolyPhen benign (0.22); catalogued as COSV66886041; called by muse, mutect2, varscan2
- PRAG1 | c.619T>C p.F207L | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.087); catalogued as COSV58160687; called by muse, mutect2, varscan2
- PXDNL | c.1391A>T p.Q464L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV62486919; called by muse, mutect2, varscan2
- RB1CC1 | c.4151A>C p.K1384T | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV50248263; called by muse, mutect2, varscan2
- RPTN | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 150/371 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768986867, COSV60166732; called by muse, mutect2, varscan2
- SCYL2 | c.925A>T p.N309Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV62568713; called by muse, mutect2, varscan2
- SERPINA6 | c.402T>A p.D134E | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV58584831; called by muse, mutect2, varscan2
- SH3BP4 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 117/297 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1159335780, COSV60643851; called by muse, mutect2, varscan2
- SHF | c.130C>A p.H44N | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV52050439; called by muse, mutect2, varscan2
- THUMPD3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as rs984722583, COSV61505965, COSV61506305; called by muse, mutect2, varscan2
- TMEM125 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.127); catalogued as COSV71326924; called by muse, mutect2, varscan2
- TMEM9 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765142412, COSV66243832; called by muse, mutect2, varscan2
- TONSL | c.381G>C p.R127S | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV68048223; called by muse, mutect2, varscan2
- TRIM8 | c.999C>A p.F333L | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.389); catalogued as COSV56660480; called by muse, mutect2, varscan2
- UBN1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52167988; called by muse, mutect2, varscan2
- UGT2B28 | c.104A>T p.H35L | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV59431917; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1856G>C p.R619P | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV54437185; called by muse, mutect2, varscan2
- UTP23 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52666616; called by muse, mutect2, varscan2
- XPOT | c.2295C>A p.F765L | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV60345205; called by muse, mutect2, varscan2
- ZCCHC14 | c.2707A>T p.S903C (on ENST00000268616; = p.S1040C on NM_015144.3) | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV51886032; called by muse, mutect2, varscan2
- ZNF221 | c.1541G>C p.R514T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.283); catalogued as COSV52108763, COSV52109241, COSV99240948; called by muse, mutect2, varscan2
- ARID1A | c.5627del p.P1876Qfs*7 | Frame Shift Del (DEL) | VAF 46/127 reads (36%) | called by mutect2, pindel, varscan2
- COL7A1 | c.6873del p.E2291Dfs*97 | Frame Shift Del (DEL) | VAF 38/97 reads (39%) | called by mutect2, varscan2
- DNPH1 | c.376+3G>T | Splice Region (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- IL17RD | c.357del p.K119Nfs*10 | Frame Shift Del (DEL) | VAF 32/91 reads (35%) | called by mutect2, pindel, varscan2
- ANGPTL8 | c.75C>T p.G25= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs376063419; called by muse, mutect2, varscan2
- C15orf39 | c.1278C>T p.C426= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as COSV62296641; called by muse, mutect2, varscan2
- C19orf71 | c.565C>T p.L189= | Silent (SNP) | VAF 114/330 reads (35%) | catalogued as COSV61535503; called by muse, mutect2
- CCDC180 | c.4116C>T p.C1372= | Silent (SNP) | VAF 114/308 reads (37%) | catalogued as rs575555258, COSV63826641; called by muse, varscan2
- CCDC198 | c.138A>T p.S46= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV53602032; called by muse, mutect2, varscan2
- CCT5 | c.1491G>A p.G497= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as rs771882069, COSV54724004; called by muse, mutect2, varscan2
- HIP1 | c.1980G>A p.T660= | Silent (SNP) | VAF 58/97 reads (60%) | catalogued as rs782382750, COSV100416693, COSV61185643; called by muse, mutect2, varscan2
- MBTPS1 | c.2685C>G p.V895= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs776882618, COSV58570064, COSV58570602; called by muse, mutect2, varscan2
- MTMR3 | c.2601C>T p.C867= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV60304173; called by muse, mutect2, varscan2
- MYO9B | c.6201G>A p.T2067= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as rs770730753, COSV55726629; called by muse, mutect2, varscan2
- SEPTIN5 | c.900C>T p.C300= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as rs759776062, COSV63530612; called by muse, mutect2, varscan2
- SLC12A2 | c.1632T>A p.V544= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV52471117; called by muse, varscan2
- SLC26A2 | c.2133T>C p.S711= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV53825110; called by muse, mutect2, varscan2
- STAC2 | c.402C>T p.N134= | Silent (SNP) | VAF 55/105 reads (52%) | catalogued as COSV61065482; called by muse, mutect2, varscan2
- ZNF366 | c.2109G>A p.R703= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV59215391; called by mutect2, varscan2
- ZNF57 | c.39C>T p.F13= | Silent (SNP) | VAF 68/154 reads (44%) | catalogued as COSV60983386; called by muse, mutect2, varscan2
- BOLA1 | chr1:149900749 T>A | 3'Flank (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100975258; called by muse, mutect2
- GNG5P2 | n.52C>A | RNA (SNP) | VAF 90/111 reads (81%) | called by muse, mutect2, varscan2
- PCSK5 | c.2626+5046C>A | Intron (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- PLOD1 | c.580-216C>T | Intron (SNP) | VAF 57/149 reads (38%) | called by muse, mutect2, varscan2
